Gene-level copy-number profile of tumor specimen HCM-BROD-0870-C43-06B from HCMI case HCM-BROD-0870-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.3 years (18,388 days).
Specimen HCM-BROD-0870-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1a8e7bbc-70d0-4bba-b072-5354f20eceb0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0870-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/6a09c5f9-81b0-46dd-bb36-ef7991b31002

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 180; copy number 2: 8,165; copy number 3: 9,107; copy number 4: 31,533; copy number 5: 4,576; copy number 6: 1,400; copy number 7: 662; copy number 8: 2,453; copy number 9: 278; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:68,228,651–68,300,035, 3 genes: AL353608.2, CBWD3, AL353608.4.
- chr14:18,333,726–18,633,634, 12 genes (within-gene range 0–2): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297.
- chr14:18,634,955–18,637,421, 2 genes (within-gene range 0–2): CR383656.1, CR383656.12.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 283 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 9: AC239800.3, LINC02591, RNU1-143P.
- chr7:99,173,574–108,130,361, 275 genes, copy number 9 (broad region; genes not listed).
- chr8:91,059,318–91,219,236, 5 genes, copy number 10 (within-gene range 8–10): OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661.

Autosomal genes at a single copy (total copy number 1): 179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
